Gene-level copy-number profile of tumor specimen HCM-BROD-0745-C43-06B from HCMI case HCM-BROD-0745-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.3 years (25,306 days).
Specimen HCM-BROD-0745-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a93a6905-c44b-4143-b37a-73c1e9e67aad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0745-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/92da46df-44ee-473e-a763-f091048378c1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 22,595; copy number 2: 34,214; copy number 3: 2,027; copy number 4: 47.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes (within-gene range 0–1): AL449423.1, CDKN2B, UBA52P6.
- chr9:64,473,040–64,498,745, 4 genes: CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr10:87,341,685–87,357,882, 1 gene (within-gene range 0–2): LINC00863.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19,740. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
